Gene-level copy-number profile of tumor specimen ALCH-AFDJ-TTP1-A from ALCHEMIST case ALCH-AFDJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 78.9 years (28,826 days).
Specimen ALCH-AFDJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3715c38e-0281-4b31-8340-959da0cb74e9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AFDJ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/26d4ec73-301a-47ae-bb4c-fcc7b67e7fce

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 547; copy number 1: 12,931; copy number 2: 41,483; copy number 3: 3,308; copy number 4: 68; copy number 5: 37; copy number 6: 6; copy number 9: 2; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 547 genes in 46 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:62,189,131–62,319,434, 7 genes: PIGPP2, RPS15AP7, L1TD1, AL162739.1, Y_RNA, KANK4, RNU6-371P.
- chr2:73,254,682–73,284,478, 1 gene: FBXO41.
- chr2:89,872,463–89,916,052, 6 genes: IGKV2D-38, IGKV1D-37, IGKV2D-36, IGKV1D-35, IGKV3D-34, IGKV1D-33.
- chr2:90,121,786–91,621,421, 16 genes (within-gene range 0–1): IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1.
- chr4:49,203,171–49,589,529, 19 genes: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr5:97,336,858–97,337,040, 1 gene (within-gene range 0–2): AC074133.1.
- chr6:39,299,001–39,322,968, 2 genes: KCNK17, KCNK16.
- chr6:39,353,747–39,354,172, 1 gene (within-gene range 0–2): AL136087.1.
- chr7:140,435,316–140,479,536, 2 genes: AC069335.1, MKRN1.
- chr8:37,784,191–37,899,497, 4 genes: ADGRA2, BRF2, RAB11FIP1, AC130304.1.
- chr9:19,409,009–19,894,856, 6 genes: ACER2, AL158206.1, MAP1LC3BP1, SLC24A2, C11orf98P1, AL158077.2.
- chr9:21,201,469–21,699,596, 29 genes: IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P.
- chr9:60,914,407–68,644,442, 170 genes (broad region; genes not listed).
- chr9:123,402,525–123,493,156, 3 genes (within-gene range 0–3): MIR601, MIR7150, AL445489.1.
- chr10:42,149,310–42,281,819, 5 genes: KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8.
- chr11:47,164,299–47,449,143, 19 genes (within-gene range 0–2): ARFGAP2, AC090589.3, PACSIN3, MIR6745, AC090589.1, DDB2, AC018410.1, ACP2, NR1H3, MADD, MADD-AS1, AC090582.1, MYBPC3, SPI1, AC090559.1, MIR4487, SLC39A13, PSMC3, RAPSN.
- chr11:70,467,856–71,524,107, 16 genes (within-gene range 0–1): SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P, DHCR7, AP002387.1, NADSYN1, MIR6754, AP000867.2.
- chr11:77,066,961–77,215,241, 3 genes: CAPN5, OMP, MYO7A.
- chr12:48,766,194–48,790,535, 4 genes: AC117498.1, ADCY6, MIR4701, ADCY6-DT.
- chr12:53,962,308–54,056,030, 20 genes: HOTAIR, AC012531.5, AC012531.7, AC012531.4, AC012531.6, HOXC11, HOXC-AS3, HOXC10, AC012531.3, HOXC6, MIR196A2, HOXC-AS2, HOXC9, HOXC-AS1, HOXC8, HOXC4, AC012531.2, AC012531.1, HOXC5, MIR615.
- chr13:111,316,184–112,321,758, 11 genes: TEX29, AL359649.1, LINC02337, LINC00354, AL138691.1, SOX1-OT, SOX1, AL356961.1, LINC00404, LINC01070, LINC01043.
- chr14:18,333,726–19,677,923, 60 genes (within-gene range 0–2): CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10, NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2, POTEM, AL929601.3, RNU6-1239P, AL589182.1, GRAMD4P4, DUXAP9, AL589182.3, AL589743.3, NBEAP5, AL589182.2, OR11H13P, AL589743.2, AL589743.4, CDRT15P13, NBEAP6, AL589743.1, TOMM40P1, DUXAP10, BMS1P17, AL929602.1, LINC01297, GRAMD4P3, POTEG, AL512624.2, RNU6-1268P, MED15P6, NF1P4, AL512310.11, AL512624.1, NF1P11, AL512310.3, AL512310.10, AL512310.8.
- chr14:67,441,855–67,441,930, 1 gene: MIR5694.
- chr14:93,138,066–93,138,465, 1 gene: CYB5AP3.
- chr14:99,604,556–99,625,740, 1 gene: AL160313.1.
- chr15:25,232,387–25,250,940, 11 genes (within-gene range 0–1): SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:41,825,099–41,899,528, 8 genes (within-gene range 0–1): AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310, AC020659.1.
- chr15:65,895,079–66,253,747, 2 genes: MEGF11, MIR4311.
- chr15:73,730,048–73,889,214, 5 genes: AC022188.1, INSYN1, INSYN1-AS1, AC018943.1, TBC1D21.
- chr15:77,568,970–77,820,900, 6 genes: AC046168.2, LINGO1, LINGO1-AS1, LINGO1-AS2, AC105133.2, AC105133.1.
- chr15:99,395,179–99,498,375, 5 genes: LINC02244, AC015660.2, AC015660.3, AC015660.1, AC015660.4.
- chr16:16,149,565–16,223,522, 1 gene (within-gene range 0–2): ABCC6.
- chr16:46,884,362–46,931,289, 1 gene: GPT2.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:22,298,691–22,332,410, 2 genes: FAM27E5, AC087575.1.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–2): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr19:24,004,358–24,163,425, 7 genes: RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1.
- chr20:47,656,348–47,786,616, 2 genes (within-gene range 0–2): SULF2, AL354813.1.
- chr20:64,034,344–64,039,962, 1 gene (within-gene range 0–1): C20orf204.
- chr21:7,744,962–13,120,807, 74 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 46 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:22,428,838–22,531,157, 2 genes, copy number 5: ZBTB40, ZBTB40-IT1.
- chr5:135,802,985–135,803,075, 1 gene, copy number 5: MIR5692C1.
- chr6:32,549,940–32,589,848, 3 genes, copy number 5: RNU1-61P, HLA-DRB6, HLA-DRB1.
- chr7:70,972–95,683, 2 genes, copy number 5 (within-gene range 4–5): AC093627.1, AC093627.6.
- chr7:76,531,319–76,541,459, 1 gene, copy number 15 (within-gene range 3–15): SPDYE16.
- chr8:143,915,153–143,976,734, 2 genes, copy number 5: PLEC, MIR661.
- chr17:18,450,244–18,475,920, 4 genes, copy number 6–9: KRT16P4, AL353997.1, AL353997.4, TNPO1P2.
- chr17:18,497,095–18,551,705, 4 genes, copy number 5 (within-gene range 2–5): NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr17:39,757,718–39,877,896, 4 genes, copy number 5: IKZF3, KRT8P34, AC090844.1, ZPBP2.
- chr19:840,999–975,939, 10 genes, copy number 5: PRTN3, ELANE, CFD, MED16, RNU6-9, R3HDM4, KISS1R, ARID3A, AC005379.1, AC005391.1.
- chr19:999,796–1,106,791, 11 genes, copy number 5–6 (within-gene range 5–9): AC004528.1, GRIN3B, TMEM259, AC004528.2, RNU6-2, CNN2, AC011558.1, ABCA7, ARHGAP45, POLR2E, GPX4.
- chr20:62,796,473–62,805,587, 2 genes, copy number 5 (within-gene range 4–5): MRGBP, OGFR-AS1.

Autosomal genes at a single copy (total copy number 1): 12,924. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
